Gene-level copy-number profile of tumor specimen TCGA-G3-AAV7-01A from TCGA case TCGA-G3-AAV7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 39.0 years (14,229 days).
Specimen TCGA-G3-AAV7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.a83eb142-7cad-4d51-92c5-75f7e12da124.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-AAV7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/607fba17-c1e3-43b0-9afd-5f4f49541205

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 22,828; copy number 2: 32,352; copy number 3: 1,836; copy number 4: 2,757; copy number 5: 34; copy number 6: 4; copy number 7: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G3-AAV7-01A-11D-A381-01): tumor purity 0.65, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:93,309,669–93,395,855, 2 genes: AL160159.1, HNRNPA1P29.
- chr16:72,236,281–72,665,014, 4 genes (within-gene range 0–1): LINC01572, AC009075.2, U6, AC004158.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:61,143,656–61,153,962, 1 gene, copy number 5: LINC02271.
- chr4:61,211,652–61,428,221, 2 genes, copy number 5: RPL17P19, AC020741.1.
- chr5:12,297,399–12,297,504, 1 gene, copy number 5: RNU6-679P.
- chr17:14,834,557–14,957,216, 2 genes, copy number 7 (within-gene range 1–7): LINC02096, RPL23AP76.

Autosomal genes at a single copy (total copy number 1): 21,491. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
